Gene-level copy-number profile of tumor specimen ALCH-B40Y-TTP1-A from ALCHEMIST case ALCH-B40Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,415 days).
Specimen ALCH-B40Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d81466ae-2424-472f-8fcf-89a0bdf520e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,260 have no estimate.
https://portal.gdc.cancer.gov/files/15265081-d197-4cef-b1bb-fda117fe1376

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 415; copy number 2: 56,561; copy number 3: 1,340; copy number 4: 26; copy number 5: 7; copy number 6: 1; copy number 7: 12; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,234,385–9,236,046, 1 gene, copy number 7: USP17L15.
- chr4:9,272,364–9,369,070, 11 genes, copy number 7: USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P.
- chr14:18,333,726–18,341,859, 1 gene, copy number 5: CR383658.1.
- chr16:33,345,182–33,496,093, 6 genes, copy number 5: AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5.
- chr21:8,680,538–8,680,934, 1 gene, copy number 8: CR381572.2.
- chr21:10,136,419–10,137,004, 1 gene, copy number 6: CDRT15P8.

Autosomal genes at a single copy (total copy number 1): 415. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
